TCGA case TCGA-FF-8061 — Lymphoid Neoplasm Diffuse Large B-cell Lymphoma (TCGA-DLBC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mature B-Cell Lymphomas; Primary site: Small intestine; Tissue source site: SingHealth. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c8cde9ea-89e9-4ee8-8a46-417a48f6d3ab

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: Singapore; Age at index: 42 years; Vital status: Alive.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; ICD-10 code: C83.3; Tissue or organ of origin: Small intestine, NOS; Site of resection or biopsy: Small intestine, NOS; Classification of tumor: primary; Age at diagnosis: 42.0 years (15,358 days); Year of diagnosis: 2010; AJCC staging edition: 7th; Ann Arbor clinical stage: Stage II; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 832 days (2.3 years); Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Small intestine; Sites of involvement: Lymph Node, Mesenteric / Small intestine.
   Pathology details: Bone marrow malignant cells: No; Consistent pathology review: Yes; Greatest tumor dimension: 15 cm; Measurement unit: Centimeters.
   Pathology details: Additional pathology findings: Percent follicular component <= 10%.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Etoposide + Prednisone + Rituximab + Vincristine; Initial disease status: Initial Diagnosis; Regimen or line of therapy: EPOCH-R; Days to treatment start: 24 days; Days to treatment end: 154 days; Number of cycles: 6.
   Recorded as not given: adjuvant Radiation Therapy, NOS; Stem Cell Transplantation, NOS.

Follow-up (4 entries)
- Days to follow up: 433 days (1.2 years); Disease response: Tumor Free.
- Days to follow up: 832 days (2.3 years); Disease response: Tumor Free.
- Imaging type: PET; Imaging result: Negative; Timepoint: Within 2 Months After Completion of First-Course Treatment.
- ECOG performance status: 0.

Molecular and laboratory tests
- BCL2 (FISH): Normal.
- BCL2 (IHC): Positive.
- BCL6 (FISH): Normal.
- BCL6 (IHC): Positive.
- CCND1 (FISH): Normal.
- CD10 (IHC): Positive.
- CD20 (IHC): Positive.
- IGH translocation (FISH): Positive.
- IRF4 (IHC): Positive.
- MALT1 (FISH): Normal.
- MYC (FISH): Normal.
- PAX5 (FISH): Normal.
- PAX5 (IHC): Positive.
- Lactate Dehydrogenase 414 IU [Blood test normal range upper: 380].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 48.1 kg; Height: 171 cm; BMI: 16.4.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-FF-8061-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.7; Intermediate dimension: 0.6; Shortest dimension: 0.4.
  Slide TCGA-FF-8061-01A-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
  Slide TCGA-FF-8061-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15.
- Sample TCGA-FF-8061-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-FF-8061-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Diffuse large B-cell lymphoma (DLBCL) NOS (any anatomic site nodal or extranodal); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Primary pathology: Follicular component percent: < or = 10%; Extranodal site involvement: 1.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: mesenteric.
- Tests performed: LDH level: 414; Mib 1 positive percent range: 76 - 100%.
- Tests performed, Genetic testing results, Genetic testing result 1: Immunopheotypic analysis tested: CD10 > 30%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunopheotypic analysis tested: BCL2; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunopheotypic analysis tested: CD20; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunopheotypic analysis tested: MUM1 > 30%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunopheotypic analysis tested: BCL6 > 30%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunopheotypic analysis tested: PAX5; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 1: Genetic abnormality tested: C-myc; Genetic abnormality tested other: PAX5.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 2: Genetic abnormality tested: BCL2; Genetic abnormality tested other: IGH.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 3: Genetic abnormality tested: BCL6.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 4: Genetic abnormality tested: CCND1.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 5: Genetic abnormality tested: MALT1.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Follow-up form, New tumor event: Treatment outcome at TCGA followup: Complete Remission/Response.
- Drug treatment 1: Stem cell transplantation: No; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify).
- Drug treatment 2: Pharmaceutical therapy drug name: Epoch; Stem cell transplantation: No; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify).

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 832 days; disease-specific survival: no event (censored), 832 days; disease-free interval: no event (censored), 832 days; progression-free interval: no event (censored), 832 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-FF-8061-01A-11D-2209-01): tumor purity 0.79, ploidy 2, whole-genome doublings 0.
